Somatic mutation profile of tumor specimen TCGA-ZH-A8Y2-01A (aliquot TCGA-ZH-A8Y2-01A-11D-A417-09) from TCGA case TCGA-ZH-A8Y2, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.5 years (21,743 days).
Specimen TCGA-ZH-A8Y2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68c4018b-fc71-43ee-ba2f-f4d85e5bcdb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y2-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y2-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeeb952d-de53-4c63-b836-2a45710b6f5c

The open-access MAF lists 51 somatic variants for this specimen: 44 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 6, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAF | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 35/52 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV51691227, COSV51692413; called by muse, mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 43/90 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- SOX2 | c.70_89del p.N24Rfs*65 | Frame Shift Del (DEL) | VAF 9/14 reads (64%) | catalogued as rs398123693; ClinVar: pathogenic; called by mutect2, varscan2
- ADGRA1 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV66925348; called by muse, varscan2
- ATAD5 | c.4976T>C p.L1659S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1347291696; called by muse, mutect2, varscan2
- DGKI | c.2527A>G p.M843V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772915688; called by muse, mutect2
- FRY | c.2782C>A p.P928T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV66568599; called by muse, mutect2, varscan2
- ITPKB | c.1305dup p.R436Afs*105 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs766562741; called by mutect2, pindel, varscan2
- MAP3K14 | c.1404C>A p.F468L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as COSV60924255; called by muse, mutect2, varscan2
- NEB | c.16636G>C p.D5546H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422204268; called by muse, mutect2, varscan2
- PAGE2B | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs1230699919; called by muse, mutect2, varscan2
- PRKAA2 | c.148_151del p.Q50Rfs*5 | Frame Shift Del (DEL) | VAF 39/263 reads (15%) | catalogued as rs768700220; called by mutect2, pindel, varscan2
- SLITRK2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100157737; called by muse, mutect2
- TBXT | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs368969464; called by muse, mutect2, varscan2
- TRIM39 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs760615280; called by muse, mutect2, varscan2
- ZNF98 | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs867646673, COSV100757562; called by muse, mutect2
- ATM | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- BAP1 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNG5 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CAMTA1 | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.437); called by muse, mutect2
- CDHR2 | c.740C>A p.S247* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- CHTF18 | c.2328G>A p.V776= | Splice Region (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- DNAAF3 | c.676C>T p.H226Y (on ENST00000524407 / NM_001256715.2; = p.H273Y on NM_178837.4) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ECPAS | c.887T>C p.M296T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.34); called by mutect2, varscan2
- EP400 | c.4376C>G p.S1459C | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- FAM50B | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- HCN1 | c.1688dup p.L564Tfs*21 | Frame Shift Ins (INS) | VAF 117/201 reads (58%) | called by mutect2, pindel, varscan2
- HDGF | c.711T>A p.H237Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- HECW2 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HEPH | c.2825C>T p.T942I (on ENST00000343002; = p.T675I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HLA-DMA | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IPO5 | c.1002-1G>A p.X334_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- KIAA1586 | c.1063G>C p.V355L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCNT | c.1340T>C p.L447P | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- POLR3C | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.151); called by muse, mutect2
- SH3GLB1 | c.669C>G p.H223Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SLC9A3 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SLC9A9 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLCO3A1 | c.1509C>A p.S503R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2
- SMARCD1 | c.694_710del p.K232* | Frame Shift Del (DEL) | VAF 24/38 reads (63%) | called by mutect2, pindel, varscan2
- TTN | c.68727A>T p.K22909N (on ENST00000591111; = p.K15485N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | PolyPhen benign (0.348); called by muse, mutect2, varscan2
- UNC79 | c.5239C>T p.R1747* (on ENST00000393151 / NM_001346218.2; = p.R1570* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 19/23 reads (83%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ZC3H7B | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.17); called by muse, mutect2
- F2RL1 | c.345C>T p.A115= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV56996007; called by muse, mutect2, varscan2
- PPA1 | c.147A>G p.E49= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- RECQL4 | c.1632G>A p.L544= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- RSPH10B | c.192T>C p.V64= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- TMEM273 | c.22C>T p.L8= | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- ZIC3 | c.549G>A p.Q183= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.254+9837C>T | Intron (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
